Somatic mutation profile of tumor specimen 2ddefa4f-77aa-416f-93f3-904e07 (aliquot 2ddefa4f-77aa-416f-93f3-904e07_D6) from CPTAC case 11BR080, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.3 years (24,941 days).
Specimen 2ddefa4f-77aa-416f-93f3-904e07: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1baaa738-046f-436a-889b-4c74ad8982ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 7cfd025a-e4e5-48ac-b44b-56a114 (Blood Derived Normal), aliquot 7cfd025a-e4e5-48ac-b44b-56a114_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d45baa05-8b50-4c6d-ba0b-ecf26dffa189

The open-access MAF lists 37 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, Nonsense Mutation 4, Frame Shift Del 2, 3'UTR 2, In Frame Del 1, 3'Flank 1, 5'Flank 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 32/166 reads (19%) | hotspot (GDC flag); catalogued as rs3092891, CM900192, CX011720, COSV57295313; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 129/311 reads (41%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGAP5 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 47/388 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.796); catalogued as rs773341191; called by muse, mutect2, varscan2
- CD5L | c.597A>C p.K199N | Missense Mutation (SNP) | VAF 81/659 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV63822346, COSV63822577; called by muse, mutect2, varscan2
- CPSF1 | c.4027G>A p.G1343S | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782242354, COSV58233624; called by muse, mutect2
- DRAXIN | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as rs200506043, COSV53841843; called by muse, mutect2, varscan2
- ERP29 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.071); catalogued as rs1003499004; called by muse, mutect2, varscan2
- FLG | c.6611G>C p.R2204T | Missense Mutation (SNP) | VAF 88/587 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV100911303; called by muse, mutect2, varscan2
- MBD6 | c.2632C>T p.R878* | Nonsense Mutation (SNP) | VAF 31/144 reads (22%) | catalogued as COSV63074460; called by muse, mutect2, varscan2
- NHLRC2 | c.858A>G p.I286M | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs1564853893; called by muse, mutect2, varscan2
- SETD1B | c.5704C>A p.R1902S | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57350395; called by muse, mutect2
- TNKS | c.2630C>T p.A877V | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100128144; called by muse, mutect2, varscan2
- CSDE1 | c.888_890del p.E296_L297delinsD (on ENST00000358528 / NM_001007553.3; = p.E265_L266delinsD on NM_007158.6) | In Frame Del (DEL) | VAF 66/498 reads (13%) | called by mutect2, varscan2
- CSPP1 | c.3049C>T p.H1017Y (on ENST00000676605; = p.H976Y on NM_024790.6) | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- CTTNBP2 | c.4966G>T p.E1656* | Nonsense Mutation (SNP) | VAF 43/407 reads (11%) | called by muse, mutect2, varscan2
- DYRK3 | c.1552_1556delinsC p.R518Pfs*15 | Frame Shift Del (DEL) | VAF 53/296 reads (18%) | called by pindel, varscan2*
- MET | c.3977T>C p.M1326T | Missense Mutation (SNP) | VAF 385/970 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MUC16 | c.18286_18287del p.V6096Ffs*11 | Frame Shift Del (DEL) | VAF 50/199 reads (25%) | called by mutect2, pindel, varscan2
- NGDN | c.920A>C p.K307T | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NLRP4 | c.2852C>A p.A951D | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PELI2 | c.808A>G p.I270V | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PRKDC | c.6164G>T p.S2055I | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2
- TCF4 | c.1039A>T p.T347S | Missense Mutation (SNP) | VAF 22/269 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- TRRAP | c.10741A>G p.M3581V (on ENST00000359863 / NM_001244580.1; = p.M3552V on NM_003496.3) | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, varscan2
- DCHS1 | c.5763G>A p.Q1921= | Silent (SNP) | VAF 62/448 reads (14%) | called by muse, mutect2, varscan2
- GPER1 | c.828C>T p.N276= | Silent (SNP) | VAF 79/186 reads (42%) | catalogued as rs200314011, COSV52468457; called by muse, mutect2, varscan2
- IFNA1 | c.237C>G p.V79= | Silent (SNP) | VAF 94/494 reads (19%) | called by muse, mutect2
- ITPKC | c.1731G>A p.V577= | Silent (SNP) | VAF 9/117 reads (8%) | called by muse, mutect2
- KCNJ6 | c.441A>C p.I147= | Silent (SNP) | VAF 28/191 reads (15%) | called by muse, mutect2, varscan2
- MARS2 | c.132C>T p.R44= | Silent (SNP) | VAF 84/237 reads (35%) | called by muse, mutect2, varscan2
- MED23 | c.1641G>T p.V547= | Silent (SNP) | VAF 40/354 reads (11%) | called by muse, mutect2, varscan2
- AC008758.3 | n.460G>A | RNA (SNP) | VAF 43/166 reads (26%) | catalogued as rs774530922; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505189 A>G | 5'Flank (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- IL1RAP | chr3:190656280 G>T | 3'Flank (SNP) | VAF 58/630 reads (9%) | catalogued as COSV50760171; called by muse, mutect2
- KCNQ2 | c.*24G>A | 3'UTR (SNP) | VAF 17/80 reads (21%) | catalogued as rs778577821; called by muse, mutect2, varscan2
- SPAG11B | c.*22G>A | 3'UTR (SNP) | VAF 84/503 reads (17%) | called by muse, mutect2, varscan2
- TBC1D4 | c.-13T>G | 5'UTR (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
